Somatic mutation profile of tumor specimen TCGA-CV-6956-01A (aliquot TCGA-CV-6956-01A-21D-2012-08) from TCGA case TCGA-CV-6956, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.7 years (24,720 days).
Specimen TCGA-CV-6956-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8780fd87-ddcc-4694-bc7f-ca9341212bb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6956-10A (Blood Derived Normal), aliquot TCGA-CV-6956-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5b0e014-24ed-406b-ad89-e188e162d105

The open-access MAF lists 210 somatic variants for this specimen: 145 protein-altering or splice-affecting, 62 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 62, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, Nonstop Mutation 2, Intron 2, In Frame Del 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEL2 | c.2874G>A p.W958* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs1566783684, COSV100045904, COSV58565986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 39/68 reads (57%) | catalogued as rs797045057, CM043040, CM051589, COSV61774888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1057519934, COSV55876538, COSV55894288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV100400836, COSV58228732; called by muse, mutect2, varscan2
- AFTPH | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV53217345; called by muse, mutect2, varscan2
- AGO1 | c.1474T>G p.Y492D | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV64595095; called by muse, mutect2, varscan2
- AIDA | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs1482139967, COSV100388227; called by muse, mutect2, varscan2
- ANO4 | c.2835G>C p.K945N (on ENST00000392977 / NM_001286615.2; = p.K910N on NM_178826.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as rs1488925132, COSV54592898; called by muse, mutect2, varscan2
- APLP1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as rs142258705; called by muse, mutect2, varscan2
- APLP2 | c.1685A>G p.D562G | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV53840348; called by muse, mutect2, varscan2
- ARMC4 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1295384886, COSV59461588; called by muse, mutect2, varscan2
- ATP2B3 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as COSV99684253; called by muse, mutect2, varscan2
- CASP7 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.187); catalogued as rs566556942, COSV61881579; called by muse, mutect2, varscan2
- CD34 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60412610, COSV60412836; called by muse, mutect2, varscan2
- CFAP251 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.011); catalogued as COSV56609676; called by muse, mutect2, varscan2
- CLSTN2 | c.2313C>A p.C771* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV71720255; called by muse, mutect2, varscan2
- CNTROB | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58049719, COSV58050123; called by muse, mutect2, varscan2
- COL6A3 | c.1927C>G p.L643V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55086552; called by muse, mutect2, varscan2
- CPS1 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV51807787; called by muse, mutect2, varscan2
- CR1 | c.4330G>A p.V1444I | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV100887567; called by muse, mutect2, varscan2
- CSPG4 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs376877916, COSV57900862; called by muse, mutect2, varscan2
- CST3 | c.440A>T p.*147Lext*68 | Nonstop Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as rs1181117681, COSV65361943; called by muse, mutect2, varscan2
- CUX2 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55629691; called by muse, mutect2, varscan2
- DCAF12L1 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100948265; called by muse, mutect2, varscan2
- DEFB114 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs754276819, COSV100435362, COSV59037751; called by muse, mutect2, varscan2
- DNAH5 | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 24/99 reads (24%) | catalogued as rs369193065; called by muse, mutect2, varscan2
- DOCK9 | c.923G>A p.G308D (on ENST00000376460 / NM_001366676.2; = p.G309D on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs979082929, COSV59624264, COSV59625792; called by muse, mutect2, varscan2
- DRD5 | c.1246A>C p.N416H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.754); catalogued as COSV58577633; called by muse, mutect2, varscan2
- DUSP26 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs141858173; called by muse, mutect2, varscan2
- EARS2 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54841654; called by muse, mutect2, varscan2
- EPHA6 | c.2854G>C p.D952H | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67568781; called by muse, mutect2, varscan2
- EYS | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV100676369; called by muse, mutect2, varscan2
- FAM184A | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58853532; called by muse, mutect2, varscan2
- FAT1 | c.8981T>G p.L2994R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV71673395; called by muse, mutect2, varscan2
- FBXL19 | c.1870C>G p.P624A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV100590947, COSV57943859; called by muse, mutect2, varscan2
- FOSB | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62278648; called by muse, mutect2, varscan2
- FRG2C | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as rs1340832327; called by mutect2, varscan2
- GABRA3 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64797666; called by muse, mutect2, varscan2
- GPR75 | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs765133450, COSV61826431; called by muse, mutect2, varscan2
- GPRIN2 | c.269G>C p.W90S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.415); catalogued as COSV100966373; called by muse, mutect2, varscan2
- GRAP2 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100702972; called by muse, mutect2, varscan2
- HSPA8 | c.1790A>T p.K597I | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99914366; called by muse, mutect2, varscan2
- HTR7 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.224); catalogued as COSV53285584, COSV53286065; called by muse, mutect2, varscan2
- ICE2 | c.1524G>C p.L508F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.101); catalogued as COSV55034827; called by muse, mutect2, varscan2
- IGKV1D-43 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs574883099; called by muse, mutect2, varscan2
- ITGA8 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV65227471; called by muse, mutect2, varscan2
- ITPR2 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV67267993; called by muse, mutect2, varscan2
- KALRN | c.5743C>T p.P1915S (on ENST00000360013 / NM_001024660.4; = p.P218S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.953); catalogued as COSV52254659; called by muse, mutect2, varscan2
- KRT25 | c.497A>C p.D166A | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV56444502; called by muse, mutect2, varscan2
- KRT78 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs1395525814, COSV100467220; called by muse, mutect2, varscan2
- LAPTM5 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53853059; called by muse, mutect2, varscan2
- LCORL | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV58834712; called by muse, mutect2, varscan2
- LIFR | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756414449, COSV54700169; called by muse, mutect2, varscan2
- MARCHF10 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV60886541; called by muse, mutect2, varscan2
- MARCHF4 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767894408, COSV99814303; called by muse, mutect2, varscan2
- MAZ | c.1242C>G p.S414R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99361087; called by muse, mutect2, varscan2
- MCF2L2 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100193507, COSV61052246; called by muse, mutect2, varscan2
- MCOLN3 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV62013823; called by muse, mutect2, varscan2
- MELTF | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768150503, COSV99586134; called by muse, mutect2, varscan2
- MGAM | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.159); catalogued as rs567166329, COSV101527470; called by muse, varscan2
- MICU3 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100536292, COSV58845418, COSV58845768; called by muse, mutect2, varscan2
- MMP21 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM1511600, COSV100916678; called by muse, mutect2, varscan2
- MUC16 | c.3322G>C p.D1108H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV67460213; called by muse, mutect2, varscan2
- MYCBP2 | c.13192C>T p.L4398F (on ENST00000357337; = p.L4436F on NM_015057.5) | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62015781; called by muse, mutect2, varscan2
- MYO16 | c.931T>A p.W311R | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51788322, COSV51797474; called by muse, mutect2, varscan2
- MYO1A | c.2006G>C p.G669A | Missense Mutation (SNP) | VAF 111/363 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV55653278; called by muse, mutect2, varscan2
- MYO7B | c.4217T>A p.L1406Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101268130; called by muse, mutect2, varscan2
- NARS1 | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as COSV56876614, COSV56876911; called by muse, mutect2, varscan2
- NAV2 | c.5003A>G p.H1668R (on ENST00000396087 / NM_001244963.2; = p.H1612R on NM_145117.5) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60658566; called by muse, mutect2, varscan2
- NBEA | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV59763242; called by muse, mutect2, varscan2
- NCBP1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64316427, COSV64316645; called by muse, mutect2, varscan2
- NEB | c.15599C>A p.A5200D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51114828; called by muse, mutect2, varscan2
- NIN | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200932073; called by muse, mutect2, varscan2
- NIPBL | c.6742A>G p.M2248V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV56949186; called by muse, mutect2, varscan2
- NLRP11 | c.2401T>C p.F801L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789721; called by muse, mutect2, varscan2
- NRIP1 | c.744A>T p.E248D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV59657857; called by muse, mutect2, varscan2
- NUTM1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); catalogued as COSV61548746; called by muse, mutect2, varscan2
- OR10S1 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs774993378, COSV73342744; called by muse, mutect2, varscan2
- OR1J2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.044); catalogued as COSV58945228; called by muse, mutect2, varscan2
- OR5D16 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs776782822, COSV101003931, COSV65721463; called by muse, mutect2, varscan2
- PCDHGB4 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99537245; called by muse, mutect2, varscan2
- PDGFRB | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55803716; called by muse, mutect2, varscan2
- PHF21B | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs377570315, COSV57555361; called by muse, mutect2, varscan2
- PKD1L1 | c.4297G>C p.E1433Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs749229906, COSV56962975, COSV56971366; called by muse, mutect2, varscan2
- PKHD1L1 | c.6128T>A p.L2043H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.748); catalogued as COSV65741362; called by muse, mutect2, varscan2
- PLBD1 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV53692854; called by muse, mutect2, varscan2
- PLCL2 | c.2021G>A p.R674K (on ENST00000615277 / NM_001144382.2; = p.R548K on NM_015184.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67621678; called by muse, mutect2, varscan2
- PLEKHH3 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.117); catalogued as COSV99257534; called by muse, mutect2, varscan2
- POLE | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57678432; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2291C>G p.P764R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV99461208; called by muse, mutect2, varscan2
- PRDM14 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1474302429, COSV52571767; called by muse, mutect2, varscan2
- RACK1 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59318574; called by muse, mutect2, varscan2
- RASD1 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99245776; called by muse, mutect2, varscan2
- RFC4 | c.189A>C p.K63N | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV56216616; called by muse, mutect2, varscan2
- RIN2 | c.2792G>T p.G931V (on ENST00000255006 / NM_001242581.1; = p.G882V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV54786907; called by muse, mutect2, varscan2
- RNF17 | c.4515A>T p.E1505D | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs1425301400, COSV55038465, COSV99693479; called by muse, mutect2, varscan2
- RNF44 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV51269579; called by muse, mutect2, varscan2
- SCN3A | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 56/159 reads (35%) | catalogued as rs755690137, COSV51807520; called by muse, mutect2, varscan2
- SEC16A | c.3677G>A p.S1226N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755543118, COSV99257806; called by muse, mutect2, varscan2
- SELP | c.1491C>G p.N497K | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as COSV55250804, COSV55257048; called by muse, mutect2, varscan2
- SKIDA1 | c.1787G>C p.R596P | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV101481295; called by muse, mutect2, varscan2
- SLAMF6 | c.160A>C p.T54P | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV63586922; called by muse, mutect2, varscan2
- SLCO1A2 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56600511; called by muse, mutect2, varscan2
- SLIT2 | c.4260G>T p.K1420N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs111791287, COSV56568846; called by muse, mutect2, varscan2
- SMARCA1 | c.2769A>C p.E923D | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64411598; called by muse, mutect2, varscan2
- SMG7 | c.2807G>T p.G936V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100750080, COSV61630740; called by muse, mutect2, varscan2
- SORL1 | c.3338-2A>T p.X1113_splice | Splice Site (SNP) | VAF 56/168 reads (33%) | catalogued as COSV52752805; called by muse, mutect2, varscan2
- SPECC1 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99821863; called by muse, mutect2, varscan2
- SPEN | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1420284607, COSV65360627; called by muse, mutect2, varscan2
- SRGAP1 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100754633; called by muse, mutect2, varscan2
- STAG1 | c.1856A>G p.Q619R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV52625851; called by muse, mutect2, varscan2
- SUPV3L1 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV62845116; called by muse, mutect2, varscan2
- SYDE1 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54618951; called by muse, mutect2, varscan2
- SYK | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748067972, COSV65326644; called by muse, mutect2, varscan2
- SYN3 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60506163; called by muse, mutect2, varscan2
- SYVN1 | c.1383G>T p.M461I (on ENST00000377190 / NM_172230.3; = p.M460I on NM_032431.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53695161; called by muse, mutect2, varscan2
- TARS2 | c.1921C>A p.L641M | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV60872535; called by muse, mutect2, varscan2
- TEX101 | c.340T>C p.C114R (on ENST00000598265 / NM_001130011.3; = p.C132R on NM_031451.4) | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53661681; called by muse, mutect2, varscan2
- TEX2 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.904); catalogued as COSV51979820; called by muse, mutect2, varscan2
- TMEM67 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV60038284; called by muse, mutect2, varscan2
- TMEM87A | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs374342321; called by muse, mutect2, varscan2
- TRAPPC10 | c.703A>T p.M235L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99378504; called by muse, mutect2, varscan2
- TRIM48 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV70161001, COSV70161953; called by muse, mutect2, varscan2
- TRPM7 | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100539794; called by muse, mutect2, varscan2
- TSPYL5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as rs960194041, COSV59070957; called by muse, mutect2, varscan2
- TTC16 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as COSV58851897; called by muse, mutect2, varscan2
- TTN | c.54442G>T p.D18148Y (on ENST00000591111; = p.D10724Y on NM_003319.4) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | PolyPhen probably damaging (0.999); catalogued as COSV59995144; called by muse, mutect2, varscan2
- UBE4A | c.3104C>T p.P1035L (on ENST00000252108 / NM_001204077.2; = p.P1042L on NM_004788.4) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781927342, COSV99348118; called by muse, mutect2, varscan2
- VPS16 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV66794069; called by muse, mutect2, varscan2
- WDR17 | c.2533-1G>T p.X845_splice | Splice Site (SNP) | VAF 26/102 reads (25%) | catalogued as COSV54572163; called by muse, mutect2, varscan2
- WDR54 | c.1004G>C p.*335Sext*? | Nonstop Mutation (SNP) | VAF 75/181 reads (41%) | catalogued as COSV51962573; called by muse, mutect2, varscan2
- XYLT1 | c.1097A>T p.Y366F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV54482376; called by muse, mutect2, varscan2
- ZFAND2A | c.22A>C p.K8Q | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV100335888; called by muse, mutect2, varscan2
- ZNF134 | c.1091G>T p.R364M | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68696267; called by muse, mutect2, varscan2
- ZNF347 | c.1215A>T p.E405D | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61968386; called by muse, mutect2, varscan2
- ZNF763 | c.145G>T p.D49Y (on ENST00000358987 / NM_001367172.2; = p.D52Y on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV59687654; called by muse, mutect2, varscan2
- GGNBP2 | c.1705C>T p.H569Y | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- GTF3A | c.820_849del p.S274_G283del | In Frame Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel
- LENG9 | c.957del p.E319Dfs*14 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | called by mutect2, pindel, varscan2
- LIMD2 | c.36del p.S13Lfs*24 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- MFGE8 | c.154_161del p.S52Lfs*5 | Frame Shift Del (DEL) | VAF 28/105 reads (27%) | called by mutect2, pindel, varscan2
- NIPA2 | c.575dup p.V193Sfs*42 | Frame Shift Ins (INS) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- PTPN20 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.328_331del p.R110Wfs*12 | Frame Shift Del (DEL) | VAF 45/75 reads (60%) | called by mutect2, pindel, varscan2
- ZNF665 | c.860_892del p.G287_K298delinsE (on ENST00000600412; = p.G352_K363delinsE on NM_024733.5 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- ACAP1 | c.1437C>G p.V479= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV50135130; called by muse, mutect2, varscan2
- ACSM3 | c.1203T>G p.P401= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV55501028; called by muse, mutect2, varscan2
- ADGRV1 | c.15660C>T p.F5220= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV101315832; called by muse, mutect2, varscan2
- ANKRD26 | c.1053G>A p.S351= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs753971885, COSV65793886; called by muse, mutect2, varscan2
- ARHGEF7 | c.1092T>C p.Y364= (on ENST00000375741 / NM_001113511.2; = p.Y186= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs748328744, COSV54542027; called by muse, mutect2, varscan2
- ASB4 | c.828C>A p.A276= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV57944473; called by muse, mutect2, varscan2
- C15orf39 | c.468T>C p.D156= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV62296357; called by muse, mutect2, varscan2
- CDX1 | c.454C>A p.R152= | Silent (SNP) | VAF 104/186 reads (56%) | catalogued as COSV51567897; called by muse, mutect2, varscan2
- CELSR1 | c.1341C>A p.I447= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99418115; called by muse, mutect2, varscan2
- COL14A1 | c.2454C>T p.V818= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV99919104; called by muse, mutect2
- CSGALNACT2 | c.165G>A p.E55= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs577874758, COSV65675420, COSV65676121; called by muse, mutect2, varscan2
- DCLK2 | c.1839G>A p.P613= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs551849647, COSV56202678; called by muse, mutect2, varscan2
- DOCK8 | c.375C>T p.Y125= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV101210221; called by muse, mutect2, varscan2
- DPYD | c.1794C>G p.P598= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV64595238; called by muse, mutect2, varscan2
- ENTPD8 | c.825C>T p.L275= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100395529; called by muse, mutect2, varscan2
- EPHA3 | c.1668C>G p.L556= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60698208, COSV60726682; called by muse, mutect2, varscan2
- FAM189B | c.360T>A p.A120= | Silent (SNP) | VAF 91/211 reads (43%) | catalogued as COSV56944751; called by muse, mutect2, varscan2
- FYB2 | c.498C>A p.A166= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV58584387, COSV58585371; called by muse, mutect2, varscan2
- GPC4 | c.1251C>T p.N417= | Silent (SNP) | VAF 80/119 reads (67%) | catalogued as rs779372299, COSV63697664; called by muse, mutect2, varscan2
- GPC6 | c.1659G>T p.L553= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100988618; called by muse, mutect2, varscan2
- GULP1 | c.861A>T p.G287= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV63066834; called by muse, mutect2, varscan2
- H3C10 | c.153G>A p.E51= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV60797069, COSV60797079; called by muse, mutect2, varscan2
- HNF1A | c.1251T>A p.G417= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs758875084, COSV57461357; called by muse, mutect2, varscan2
- LRG1 | c.945G>A p.Q315= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV56703346; called by muse, mutect2, varscan2
- MC5R | c.675C>A p.A225= | Silent (SNP) | VAF 88/271 reads (32%) | catalogued as COSV100229022; called by muse, mutect2, varscan2
- MMP21 | c.678C>A p.I226= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100916677; called by muse, mutect2, varscan2
- NBEA | c.579G>A p.K193= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1242249285, COSV59776827; called by muse, mutect2, varscan2
- NR0B1 | c.309G>T p.P103= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV66764193; called by muse, mutect2, varscan2
- NR2F1 | c.840C>T p.A280= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs898140239, COSV100504671; called by muse, mutect2, varscan2
- OR11H4 | c.144C>T p.T48= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV59560460; called by muse, mutect2, varscan2
- OR8G1 | c.127C>T p.L43= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as rs765072062, COSV100422397, COSV58380892; called by muse, mutect2, varscan2
- OS9 | c.291G>A p.G97= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV57782634; called by muse, mutect2, varscan2
- OTOF | c.1954C>A p.R652= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs373864355, COSV99717509; called by muse, mutect2, varscan2
- PCDHGC3 | c.2262G>A p.P754= | Silent (SNP) | VAF 57/98 reads (58%) | catalogued as rs1454112813, COSV99339838; called by muse, mutect2, varscan2
- PDE10A | c.369A>T p.A123= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV63094880; called by muse, mutect2, varscan2
- PLEKHH3 | c.1323G>C p.R441= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99257532; called by muse, mutect2, varscan2
- PRKCH | c.747C>T p.S249= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV60647546; called by muse, mutect2, varscan2
- PRPSAP2 | c.1056C>T p.I352= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV52065403; called by muse, mutect2, varscan2
- PSG11 | c.255C>T p.D85= | Silent (SNP) | VAF 57/252 reads (23%) | catalogued as rs138426313; called by muse, mutect2, varscan2
- PTPRN2 | c.744C>T p.A248= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV101234324; called by muse, mutect2, varscan2
- PTPRS | c.5170C>T p.L1724= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs200749743, COSV53617067; called by muse, mutect2, varscan2
- RCOR1 | c.426A>G p.Q142= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV51767453; called by muse, mutect2, varscan2
- RFX6 | c.97C>T p.L33= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV60584498; called by muse, mutect2, varscan2
- RNF10 | c.1146G>T p.L382= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV58044673; called by muse, mutect2, varscan2
- RRM2B | c.517T>C p.L173= | Silent (SNP) | VAF 75/165 reads (45%) | catalogued as COSV52566462; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.312G>A p.K104= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV53448026; called by muse, mutect2, varscan2
- SEC24D | c.2928T>A p.I976= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV54878913; called by muse, mutect2, varscan2
- SERPINH1 | c.405C>T p.Y135= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100825072; called by muse, mutect2
- SLC16A6 | c.945C>T p.I315= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100517290; called by muse, mutect2, varscan2
- SLC27A6 | c.333G>A p.L111= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV52482244; called by muse, mutect2, varscan2
- SLC30A1 | c.225C>T p.I75= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100879127; called by muse, mutect2, varscan2
- SLITRK5 | c.2217C>A p.P739= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV100280693; called by muse, mutect2, varscan2
- SYNCRIP | c.1551C>T p.P517= | Silent (SNP) | VAF 90/139 reads (65%) | catalogued as rs1336303438, COSV62286875; called by muse, mutect2, varscan2
- TOX4 | c.294G>A p.G98= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV52970959, COSV99398258; called by muse, mutect2, varscan2
- TRPM7 | c.1578C>T p.C526= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs760989374, COSV100539792; called by muse, mutect2, varscan2
- UBE4A | c.3105C>T p.P1035= (on ENST00000252108 / NM_001204077.2; = p.P1042= on NM_004788.4) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99348123; called by muse, mutect2, varscan2
- ULBP2 | c.21C>A p.T7= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV66265360; called by muse, mutect2, varscan2
- VPS72 | c.615G>A p.R205= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV54860226; called by muse, mutect2, varscan2
- ZNF521 | c.708G>A p.R236= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100832053; called by muse, mutect2, varscan2
- ZNF571 | c.156G>A p.V52= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV60732807; called by muse, mutect2, varscan2
- ZNF678 | c.453A>G p.K151= (on ENST00000343776 / NM_001367910.1; = p.K206= on NM_178549.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV100652743; called by muse, mutect2, varscan2
- ZNF71 | c.1209G>T p.V403= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100045864; called by muse, mutect2, varscan2
- COPS9 | chr2:240129917 C>T | 3'Flank (SNP) | VAF 40/113 reads (35%) | catalogued as rs551865042, COSV56228042; called by muse, mutect2, varscan2
- CTDSP2 | c.412-298G>C | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as COSV101142992; called by muse, mutect2, varscan2
- IKBIP | c.297+7886A>T | Intron (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100141734, COSV54489347; called by muse, mutect2, varscan2
